CCDI case PBCPAG — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Soft Tissue Tumors and Sarcomas, NOS; Primary site: Lymph nodes.
https://portal.gdc.cancer.gov/cases/1fe0958c-7c32-4af8-93f1-dc818a2f885a

Demographics
Sex at birth: female; Race: black or african american.

Diagnoses (1)
1. Embryonal rhabdomyosarcoma, NOS: ICD-O-3 morphology code: 8910/3; Tissue or organ of origin: Lymph nodes of head, face and neck; Age at diagnosis: 3.2 years (1,181 days).

Biospecimens (3 samples)
- Sample 0DWHZ9: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DWI1C: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
- Sample 0DWI1Z: Tissue type: Tumor; Specimen type: Solid Tissue.
